Gene-level copy-number profile of tumor specimen ALCH-B3JO-TTP1-A from ALCHEMIST case ALCH-B3JO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.6 years (22,488 days).
Specimen ALCH-B3JO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0954e22c-84bd-45cd-8a87-29211edc507d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3JO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,864 have no estimate.
https://portal.gdc.cancer.gov/files/9d48b653-a4d7-49db-a35b-0bc53024413b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 776; copy number 1: 27,506; copy number 2: 27,584; copy number 3: 1,535; copy number 4: 796; copy number 5: 133; copy number 6: 209; copy number 7: 132; copy number 8: 6; copy number 9: 11; copy number 10: 50; copy number 11: 20; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 552 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,184,302–161,199,054, 1 gene (within-gene range 0–2): ADAMTS4.
- chr1:227,918,656–227,947,932, 2 genes (within-gene range 0–2): WNT9A, MIR5008.
- chr2:140,898,423–141,208,376, 4 genes (within-gene range 0–1): LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr3:4,303,304–4,414,960, 2 genes (within-gene range 0–1): SETMAR, MRPS10P2.
- chr3:11,272,309–11,557,665, 4 genes (within-gene range 0–1): ATG7, AC083855.1, AC026185.1, AC022001.1.
- chr6:26,896,952–26,898,777, 1 gene (within-gene range 0–1): POM121L6P.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–1): RNA5SP251.
- chr8:12,205,759–12,206,389, 1 gene: ENPP7P12.
- chr8:23,020,133–23,262,000, 13 genes (within-gene range 0–1): TNFRSF10B, AC107959.2, AC107959.3, AC107959.4, AC107959.5, TNFRSF10C, TNFRSF10D, TNFRSF10A-AS1, TNFRSF10A, RPL23AP55, AC100861.1, AC100861.2, CHMP7.
- chr10:67,793,770–67,794,245, 1 gene: RPL21P92.
- chr11:2,159,779–2,171,815, 2 genes (within-gene range 0–1): INS, TH.
- chr11:3,029,009–3,041,260, 1 gene (within-gene range 0–1): CARS1-AS1.
- chr11:65,592,836–65,650,918, 6 genes (within-gene range 0–1): KCNK7, MAP3K11, PCNX3, MIR4690, SIPA1, MIR4489.
- chr14:26,831,401–26,918,594, 2 genes (within-gene range 0–1): AL132718.1, MIR4307HG.
- chr14:87,634,379–87,655,294, 1 gene: LINC02330.
- chr14:94,960,277–101,218,241, 235 genes (broad region; genes not listed).
- chr14:102,922,663–103,057,549, 4 genes (within-gene range 0–1): AMN, CDC42BPB, AL117209.1, RPL13P6.
- chr14:104,085,686–106,879,812, 253 genes (broad region; genes not listed).
- chr15:19,955,300–20,047,994, 12 genes: AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B, AC127381.1.
- chr15:28,737,583–28,764,151, 2 genes (within-gene range 0–1): WHAMMP2, AC055876.4.
- chr16:649,311–667,833, 2 genes (within-gene range 0–1): WDR90, AL022341.2.
- chr16:12,545,482–12,557,694, 2 genes (within-gene range 0–1): AC131391.1, AC010333.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 545 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:44,921,077–46,822,804, 43 genes, copy number 5 (within-gene range 4–5): LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1, KRTCAP2P1, SIX2, AC093702.1, LINC01121, AC093833.1, AC009236.2, AC009236.1, SRBD1, RN7SL414P, PRKCE, PRKCE-AS1, RPL26P15, AC017006.2, AC017006.1, RPL36AP14, Metazoa_SRP, EPAS1, LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247, ATP6V1E2, RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1, LINC01118, SOCS5.
- chr2:47,789,316–47,906,498, 1 gene, copy number 6 (within-gene range 4–6): FBXO11.
- chr2:47,883,455–47,907,810, 2 genes, copy number 6: RPS27AP7, AC079807.1.
- chr2:47,939,738–47,940,218, 1 gene, copy number 7: PPIAP62.
- chr3:180,566,718–181,867,154, 30 genes, copy number 5: AC125618.1, RNU6-486P, AC068298.1, TTC14, CCDC39, CCDC39, CCDC39-AS1, AC108734.4, RN7SL229P, AC108734.3, AC108734.2, FLYWCH1P1, FXR1, AC108734.1, DNAJC19, SOX2-OT, AC083904.1, RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1.
- chr7:103,471,784–103,989,658, 1 gene, copy number 5 (within-gene range 2–5): RELN.
- chr7:106,774,955–108,995,029, 39 genes, copy number 5–6: LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr7:130,206,344–130,262,770, 2 genes, copy number 9 (within-gene range 4–9): SSMEM1, AC024085.1.
- chr8:12,290,071–12,296,180, 1 gene, copy number 5: DEFB131D.
- chr8:126,325,454–130,017,129, 50 genes, copy number 5–9 (within-gene range 5–10): AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194.
- chr8:132,570,416–133,573,861, 20 genes, copy number 6–7: LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1.
- chr8:134,190,383–135,299,719, 19 genes, copy number 6: AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591.
- chr12:2,695,765–4,538,508, 50 genes, copy number 6–10 (within-gene range 2–10): ITFG2-AS1, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4.
- chr12:10,824,960–11,171,608, 1 gene, copy number 11 (within-gene range 4–11): PRH1.
- chr12:10,845,849–11,895,377, 37 genes, copy number 10–11: PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2, PRB3, PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6.
- chr14:18,614,388–18,637,421, 5 genes, copy number 5: CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12.
- chr19:16,479,061–20,661,583, 231 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr19:55,528,611–55,580,848, 3 genes, copy number 5: SBK2, SBK3, ZNF579.
- chr21:43,461,960–43,479,534, 1 gene, copy number 15 (within-gene range 1–15): LINC00313.
- chr21:44,172,169–44,262,216, 8 genes, copy number 5–9: AP001056.2, AP001056.1, AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.

Autosomal genes at a single copy (total copy number 1): 25,533. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
